Gene-level copy-number profile of tumor specimen ALCH-AE1W-TTP1-A from ALCHEMIST case ALCH-AE1W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,712 days).
Specimen ALCH-AE1W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d2f830c-d0db-4dfd-8448-5b3fe82944a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE1W-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/70bceeb1-9718-4cf7-9545-f229254b8d1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 1,369; copy number 2: 56,725; copy number 3: 217; copy number 4: 4; copy number 5: 6; copy number 6: 1; copy number 7: 5; copy number 9: 8; copy number 10: 1; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,236,440–54,239,063, 1 gene (within-gene range 0–2): SSBP3-AS1.
- chr2:120,346,136–120,351,803, 1 gene: INHBB.
- chr5:524,109–527,448, 1 gene (within-gene range 0–2): AC106772.2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:58,597,589–58,706,297, 3 genes (within-gene range 0–2): AC010287.1, SLC38A7, AC012183.1.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr18:79,470,120–79,470,940, 1 gene (within-gene range 0–1): AC018445.1.
- chr20:63,843,436–63,843,915, 1 gene: C20orf181.
- chr21:14,000,927–14,020,725, 3 genes: NF1P3, PPP6R2P1, FRG2MP.
- chr22:18,650,023–18,719,341, 2 genes: PPP1R26P2, PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,744,017–136,800,595, 7 genes, copy number 5–6 (within-gene range 3–6): LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr22:18,400,407–18,638,405, 14 genes, copy number 7–28: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2.
- chr22:18,733,914–18,757,906, 1 gene, copy number 10: FAM230E.

Autosomal genes at a single copy (total copy number 1): 1,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
